Somatic mutation profile of tumor specimen TCGA-2G-AAHP-05A (aliquot TCGA-2G-AAHP-05A-11D-A42Y-10) from TCGA case TCGA-2G-AAHP, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Seminoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IS; Age at diagnosis: 31.9 years (11,649 days).
Specimen TCGA-2G-AAHP-05A: Sample type: Additional - New Primary; Tissue type: Tumor; Tumor descriptor: New Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2569e2bb-99b6-4b2c-97a1-7e9f9bc4a29a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2G-AAHP-10A (Blood Derived Normal), aliquot TCGA-2G-AAHP-10A-01D-A433-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c0647db3-33d1-44eb-9cb5-6a3d501cb8a1

The open-access MAF lists 20 somatic variants for this specimen: 16 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 3, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.183A>T p.Q61H | Missense Mutation (SNP) | VAF 32/158 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs17851045, COSV55498802, COSV55499223, COSV55811221; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CNKSR2 | c.746C>T p.P249L | Missense Mutation (SNP) | VAF 52/247 reads (21%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.464); catalogued as COSV99670347; called by muse, mutect2, varscan2
- NELL2 | c.359G>A p.G120D | Missense Mutation (SNP) | VAF 15/185 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs753991527, COSV61571786; called by muse, mutect2
- ARHGAP24 | c.103A>G p.T35A | Missense Mutation (SNP) | VAF 16/113 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.817); called by muse, mutect2, varscan2
- BRWD1 | c.3956A>G p.K1319R | Missense Mutation (SNP) | VAF 9/126 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.001); called by muse, mutect2
- C12orf65 | c.428A>C p.K143T | Missense Mutation (SNP) | VAF 25/226 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- DOCK11 | c.505C>G p.Q169E | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.33); PolyPhen benign (0.305); called by muse, mutect2, varscan2
- FRS2 | c.140T>C p.L47S | Missense Mutation (SNP) | VAF 24/188 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GPT2 | c.29G>C p.R10P | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- MUC19 | c.602A>G p.K201R | Missense Mutation (SNP) | VAF 27/175 reads (15%) | SIFT tolerated (0.47); PolyPhen benign (0.296); called by muse, mutect2, varscan2
- NAV1 | c.4299C>G p.I1433M | Missense Mutation (SNP) | VAF 49/385 reads (13%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.59); called by muse, mutect2, varscan2
- NSD1 | c.1382C>G p.T461R | Missense Mutation (SNP) | VAF 27/135 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.296); called by muse, mutect2, varscan2
- PDS5A | c.3927G>C p.L1309F | Missense Mutation (SNP) | VAF 15/125 reads (12%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- RYR2 | c.6069A>C p.L2023F | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (0.72); PolyPhen benign (0); called by muse, mutect2, varscan2
- ST6GALNAC1 | c.1061G>A p.S354N | Missense Mutation (SNP) | VAF 7/54 reads (13%) | PolyPhen benign (0.11); called by muse, mutect2, varscan2
- ZC3H7A | c.1724G>C p.C575S | Missense Mutation (SNP) | VAF 20/117 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LAMA5 | c.10227G>T p.G3409= | Silent (SNP) | VAF 12/50 reads (24%) | called by muse, mutect2, varscan2
- NAA16 | c.366G>T p.L122= | Silent (SNP) | VAF 17/83 reads (20%) | called by muse, mutect2, varscan2
- RNF213 | c.9366C>T p.H3122= | Silent (SNP) | VAF 25/149 reads (17%) | called by muse, mutect2, varscan2
- RNF8 | c.*66T>A | 3'UTR (SNP) | VAF 10/69 reads (14%) | called by muse, mutect2, varscan2
